Surgical pathology report (de-identified scan), TCGA case TCGA-E7-A6MD, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Asterand, specimen TCGA-E7-A6MD-01A (Primary Tumor).

[page 1 of 2]
Patient ID:

Surgical Date:

Gross Description: 1. Piece of cystoprostatectomy presenting the urinary bladder with a whitish, ulcerated and necrosed multifocal tumoral proliferation, with invasive aspect and intramural evolution. Histopathological aspect of infiltrative urothelial cell carcinoma, with high malignant potential, moderately/ poorly differentiated, G2/G3, with areas of neuroendocrine differentiation, intramural evolution and invasion of the entire bladder wall, up to the perivesical fat tissue and the prostate, with necrosis and ulceration; stpT4. Numerous intravascular tumoral emboli.

2. Right iliac commune tissue with eight (8) lymph nodes with a maximum diameter of 1.0 cm, the biggest of them with metastasis of the urothelial cell carcinoma, G2/G3, the rest with reactive aspect and sinus congestion (1+).

3. Left iliac extern, intern and obturator tissue with six (6) lymph nodes with dimensions of 0.8 cm; two of them with metastasis of the urothelial cell carcinoma, G2/G3, the rest with reactive aspect and sclero-lipomatous dystrophy (2+).

4.-5. Resection samples with preserved histological aspect.

Microscopic Description:

Diagnosis Details: CONCLUSION: Infiltrative urothelial cell carcinoma of the bladder, with high malignant potential, moderately/ poorly differentiated, G2/G3, with areas of neuroendocrine differentiation, stpT4, pN2, pMx (stage IV).

Comments:

Formatted Path Reports: BLADDER TISSUE CHECKLIST

Specimen type: Radical cystectomy

Tumor site: Bladder

Tumor size: Not specified

Tumor features: Ulcerated

Histologic type: Transitional cell carcinoma

Histologic grade: Poorly differentiated

Tumor extent: Invades to prostate

Lymph nodes: 3/14 positive for metastasis (Iliac commune and left side nodes 3/14)

Lymphatic invasion: Not specified

CCRF ICD-O-3
Carcinoma, urothelial NOS
path 8/20/13
Carcinoma, transitional cell NOS
8/20/13
Site CCRF Anterior wall of bladder C67.3
path Bladder NOS C67.9
Per TSS, specific site is bladder, wall, anterior.
9/27/13
CCRF

[page 2 of 2]
Venous invasion: Not specified

Margins: Not specified

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

Review/Initials	Date Reviewed: 7/1/13	

7/1/13

Source: NCI Genomic Data Commons file 6353cff8-ced1-4292-a81e-dfc14b75b971 (TCGA-E7-A6MD.9BDC33BB-1DF1-4B0E-A39C-1A173AC0C2CF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).